Gene-level copy-number profile of tumor specimen C3N-00737-01 (profiled together with C3N-00737-03) from CPTAC case C3N-00737, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 71.4 years (26,067 days).
Specimen C3N-00737-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb503e5f-ae3b-4cf6-9a62-f650578d3e9a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00737-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/0573a957-63fe-427b-978c-1b811f3b3a25

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 4,889; copy number 2: 42,311; copy number 3: 8,061; copy number 4: 2,716; copy number 5: 271; copy number 6: 8; copy number 7: 64; copy number 9: 31; copy number 13: 47.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 421 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,991,276–42,051,784, 90 genes, copy number 5–13 (broad region; genes not listed).
- chr1:151,197,949–155,062,775, 217 genes, copy number 5 (broad region; genes not listed).
- chr1:159,171,609–159,469,068, 12 genes, copy number 5 (within-gene range 3–5): CADM3, RNA5SP60, CADM3-AS1, ACKR1, MPTX1, OR10J2P, FCER1A, OR10J3, AL513323.1, OR10J7P, OR10J8P, OR10J9P.
- chr1:159,437,845–159,443,078, 1 gene, copy number 5 (within-gene range 3–5): OR10J1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:29,210,986–29,500,460, 4 genes, copy number 6: AL133166.1, AL158058.1, AL158058.2, RNU11-5P.
- chr14:35,121,846–40,390,547, 93 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,703. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
